Somatic mutation profile of tumor specimen TCGA-AP-A05N-01A (aliquot TCGA-AP-A05N-01A-11W-A027-09) from TCGA case TCGA-AP-A05N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 58.2 years (21,254 days).
Specimen TCGA-AP-A05N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0be0619-281a-4601-aea2-ea4bffd02800.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A05N-10A (Blood Derived Normal), aliquot TCGA-AP-A05N-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/246832f3-73fe-4a79-9039-e57fa72e2d44

The open-access MAF lists 324 somatic variants for this specimen: 249 protein-altering or splice-affecting, 66 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 66, Frame Shift Del 61, Frame Shift Ins 21, Nonsense Mutation 15, Splice Site 7, RNA 4, Intron 4, In Frame Del 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOB | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 42/120 reads (35%) | catalogued as rs1057516902, CM082486, COSV66398685; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 150/464 reads (32%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 41/112 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- ABLIM2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56399534; called by muse, mutect2, varscan2
- ACACB | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58147071; called by muse, mutect2
- ACADVL | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV50039818; called by muse, mutect2, varscan2
- ACVR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751000395, COSV55116085; called by muse, mutect2, varscan2
- ADD3 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 165/418 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53326081; called by muse, mutect2, varscan2
- ADORA1 | c.547T>G p.F183V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV55144321; called by muse, mutect2, varscan2
- AGXT2 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51486513; called by muse, mutect2, varscan2
- AIFM2 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57160989; called by muse, mutect2, varscan2
- ALK | c.2951A>G p.Y984C | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV66590180; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD26 | c.4801C>T p.L1601F | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV65778500; called by muse, mutect2, varscan2
- ANKRD26 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV65798747; called by muse, mutect2, varscan2
- AP1G2 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 79/187 reads (42%) | catalogued as COSV55339704, COSV99065591; called by muse, mutect2, varscan2
- ARF1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as rs1382592951, COSV55254161; called by muse, mutect2, varscan2
- ARFGEF1 | c.1967C>A p.P656H | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as COSV51616947, COSV51617305; called by muse, varscan2
- ARHGAP36 | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV52272151; called by muse, mutect2, varscan2
- ARHGEF6 | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 54/159 reads (34%) | catalogued as COSV51689477, COSV51696118; called by muse, mutect2, varscan2
- ARID1A | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 292/710 reads (41%) | catalogued as COSV61371604, COSV61372723; called by muse, mutect2, varscan2
- ATP6AP2 | c.846G>T p.E282D | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.253); catalogued as COSV65798380; called by muse, mutect2, varscan2
- ATR | c.5032-1G>A p.X1678_splice | Splice Site (SNP) | VAF 140/347 reads (40%) | catalogued as COSV63386541, COSV63392626; called by muse, mutect2, varscan2
- BAZ2A | c.2518C>T p.R840* | Nonsense Mutation (SNP) | VAF 45/100 reads (45%) | catalogued as COSV51643968; called by muse, mutect2, varscan2
- BOD1L1 | c.9095G>T p.G3032V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.311); catalogued as COSV50069924; called by muse, mutect2, varscan2
- C5orf51 | c.808G>T p.G270* | Nonsense Mutation (SNP) | VAF 93/239 reads (39%) | catalogued as COSV67566462; called by muse, mutect2, varscan2
- CABLES2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs1185111936, COSV54155752; called by muse, mutect2
- CALD1 | c.1621C>T p.R541C (on ENST00000361675 / NM_033138.4; = p.R286C on NM_004342.7) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1199236268, COSV62646842, COSV62654401; called by muse, mutect2, varscan2
- CARM1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1377302649, COSV59003618; called by muse, mutect2, varscan2
- CARMIL3 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs373814202; called by muse, mutect2, varscan2
- CCNO | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754329141, COSV57005185; called by muse, mutect2, varscan2
- CDH20 | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as COSV53018418; called by muse, mutect2, varscan2
- CDK12 | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV71002988; called by muse, mutect2, varscan2
- CDSN | c.714_715insA p.Y239Ifs*36 | Frame Shift Ins (INS) | VAF 29/96 reads (30%) | catalogued as COSV99456541; called by mutect2, pindel, varscan2
- CHD7 | c.4268A>G p.E1423G | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV71114752; called by muse, mutect2, varscan2
- CNST | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.151); catalogued as COSV63622503; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 60/170 reads (35%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.3340A>G p.S1114G | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as rs983036503, COSV62260858; called by muse, varscan2
- COBL | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54359101; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | catalogued as rs374805044; called by mutect2, varscan2
- COTL1 | c.401del p.G134Efs*48 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs1437232641; called by mutect2, pindel, varscan2
- CPSF1 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs782071262, COSV62940084; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 34/192 reads (18%) | catalogued as rs1378599948; called by mutect2, varscan2
- CSMD2 | c.4006G>A p.G1336R | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs368584183; called by muse, mutect2, varscan2
- CTNNBL1 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 35/236 reads (15%) | catalogued as COSV63747427; called by muse, mutect2, varscan2
- CUX1 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52916530; called by muse, mutect2, varscan2
- CYP2E1 | c.1145T>G p.L382R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV53315517; called by muse, mutect2, varscan2
- DBX2 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 52/491 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60339844; called by muse, mutect2, varscan2
- DCLK1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs775609349, COSV55212175; called by muse, mutect2, varscan2
- DCLK2 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV56212574; called by muse, mutect2, varscan2
- DDX47 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 52/318 reads (16%) | catalogued as rs372689788; called by muse, mutect2, varscan2
- DENND2B | c.1781A>G p.N594S | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as rs768715492, COSV58207940; called by muse, mutect2, varscan2
- DGKK | c.1596G>A p.G532= | Splice Region (SNP) | VAF 94/258 reads (36%) | catalogued as COSV65709456; called by muse, mutect2, varscan2
- DICER1 | c.2805-3dup | Splice Region (INS) | VAF 33/154 reads (21%) | catalogued as rs761163858; called by mutect2, pindel, varscan2
- DPAGT1 | c.698dup p.T234Hfs*116 | Frame Shift Ins (INS) | VAF 31/168 reads (18%) | catalogued as rs35482889; called by mutect2, varscan2
- DPYD | c.1887G>T p.K629N | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64615281; called by muse, mutect2, varscan2
- DYNAP | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.381); catalogued as rs752467570, COSV58667257; called by muse, mutect2, varscan2
- EGF | c.2648del p.P883Lfs*67 | Frame Shift Del (DEL) | VAF 57/345 reads (17%) | catalogued as rs758373637; called by mutect2, pindel, varscan2
- EIF4G1 | c.2323A>G p.M775V (on ENST00000346169 / NM_198241.3; = p.M580V on NM_004953.5) | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV59994074; called by muse, mutect2, varscan2
- EIF4G3 | c.4643A>C p.K1548T | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1369525095, COSV51694620; called by muse, mutect2, varscan2
- ELAVL1 | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 21/54 reads (39%) | catalogued as COSV60966132, COSV60969019; called by muse, mutect2, varscan2
- ELOC | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1401705508, COSV53024186; called by muse, mutect2, varscan2
- ENTPD6 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV61752485; called by muse, mutect2
- ERBB2 | c.1988T>C p.L663P | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54083373; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs775950025; called by mutect2, varscan2
- FAM193A | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 82/466 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780608278, COSV61198845; called by muse, mutect2, varscan2
- FAN1 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV62952196; called by muse, mutect2, varscan2
- FHDC1 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV52603084; called by muse, mutect2, varscan2
- FLG | c.8136G>T p.Q2712H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1370812162, COSV64249770; called by mutect2, varscan2
- FLG | c.4873C>T p.Q1625* | Nonsense Mutation (SNP) | VAF 26/184 reads (14%) | catalogued as COSV64249776; called by muse, mutect2, varscan2
- FLNB | c.3176C>T p.A1059V | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs570950728, COSV55896163; called by muse, mutect2, varscan2
- FNBP1 | c.1593G>T p.E531D | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.09); catalogued as COSV100852546, COSV63090886; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | catalogued as rs758551787; called by mutect2, varscan2
- GBF1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs756702754, COSV64149189; called by muse, mutect2, varscan2
- GIGYF2 | c.2829del p.L944Cfs*9 | Frame Shift Del (DEL) | VAF 97/269 reads (36%) | catalogued as COSV65253650; called by mutect2, pindel, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 94/251 reads (37%) | catalogued as rs750227570; called by mutect2, varscan2
- GNAT2 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV63555424; called by muse, mutect2
- GTF3C1 | c.4592G>A p.R1531Q | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as rs752889331, COSV62245068; called by muse, mutect2, varscan2
- GUF1 | c.1934dup p.L646Afs*8 | Frame Shift Ins (INS) | VAF 40/114 reads (35%) | catalogued as rs770418349; called by mutect2, varscan2
- HIVEP1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV65105184; called by muse, mutect2, varscan2
- HMCN1 | c.12451G>A p.A4151T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV54942939; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1784A>G p.N595S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV54567082; called by muse, mutect2, varscan2
- HOXA1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV56067843; called by muse, mutect2, varscan2
- HSPA1A | c.1876G>T p.G626C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.455); catalogued as COSV65149504; called by muse, mutect2, varscan2
- IP6K1 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57696719; called by muse, mutect2, varscan2
- IRX1 | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57362550; called by muse, mutect2, varscan2
- ITGAM | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54942845; called by muse, mutect2
- ITGAX | c.2183C>T p.T728I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV51651781; called by muse, mutect2, varscan2
- ITGB1BP2 | c.1035G>T p.M345I | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV52140437; called by muse, mutect2, varscan2
- ITGB4 | c.3368del p.P1123Lfs*37 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1441262033; called by mutect2, pindel
- ITPR1 | c.3343C>A p.Q1115K (on ENST00000354582; = p.Q1100K on NM_002222.7) | Missense Mutation (SNP) | VAF 214/587 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as COSV56982347, COSV57004552; called by muse, mutect2, varscan2
- KAT6B | c.4121G>A p.G1374E | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV54743294, COSV54745814; called by muse, mutect2, varscan2
- KHDRBS2 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 139/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55493458, COSV99028877, COSV99837140; called by muse, mutect2, varscan2
- KRT15 | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV54182074; called by muse, mutect2
- LARP1B | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV52803204; called by muse, mutect2
- LGALS9C | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV100055445; called by mutect2, varscan2
- LHB | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55487305; called by muse, mutect2, varscan2
- LHX9 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as COSV61331668; called by muse, mutect2, varscan2
- LIMK1 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554700442, COSV60280750; called by muse, mutect2
- LMBR1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754181857, COSV62223494; called by muse, mutect2, varscan2
- LMOD2 | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs758021724, COSV71755870; called by muse, mutect2, varscan2
- LRRK2 | c.2129del p.N710Mfs*2 | Frame Shift Del (DEL) | VAF 161/504 reads (32%) | catalogued as COSV54153441; called by mutect2, pindel, varscan2
- MACROH2A1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs1472687077, COSV56898270; called by muse, mutect2
- MAGI2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62641925; called by muse, mutect2
- MANEAL | c.1165C>T p.Q389* (on ENST00000373045 / NM_001113482.1; = p.Q167* on NM_152496.2) | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as COSV61116906; called by muse, mutect2, varscan2
- MAP3K21 | c.2067G>A p.W689* | Nonsense Mutation (SNP) | VAF 73/204 reads (36%) | catalogued as COSV64042683; called by muse, mutect2, varscan2
- MGA | c.7436A>G p.D2479G (on ENST00000219905 / NM_001164273.1; = p.D2270G on NM_001080541.2) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54963287; called by muse, mutect2, varscan2
- MLKL | c.527T>C p.L176S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV58206688; called by muse, mutect2, varscan2
- MYH4 | c.4475A>G p.Y1492C | Missense Mutation (SNP) | VAF 9/265 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV55126642; called by muse, mutect2
- MYL7 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV56269160; called by muse, mutect2, varscan2
- NUP205 | c.5260C>T p.Q1754* | Nonsense Mutation (SNP) | VAF 27/189 reads (14%) | catalogued as rs763494569, COSV53666364; called by muse, mutect2, varscan2
- OTUD7A | c.974C>T p.P325L (on ENST00000307050 / NM_001382637.1; = p.P318L on NM_130901.3) | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61043628; called by muse, mutect2, varscan2
- PCDHGA7 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); catalogued as rs559398944, COSV53944887; called by muse, mutect2, varscan2
- PCNT | c.5381C>T p.A1794V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100854936; called by muse, mutect2
- PDE3A | c.1701del p.Y567* | Frame Shift Del (DEL) | VAF 126/370 reads (34%) | catalogued as COSV100761740, COSV62973229, COSV62983231; called by mutect2, pindel, varscan2
- PHLPP1 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV53039019; called by muse, mutect2
- PIF1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51424609; called by muse, mutect2, varscan2
- PLB1 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs778285036, COSV59836012; called by muse, mutect2, varscan2
- PLD6 | c.646T>C p.F216L | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV58634532; called by muse, mutect2
- PLEKHG2 | c.3903del p.A1302Qfs*57 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as rs748579666; called by mutect2, pindel, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 46/132 reads (35%) | catalogued as rs765091847; called by mutect2, varscan2
- PLP1 | c.223A>T p.T75S | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV100393399, COSV58278516; called by muse, mutect2, varscan2
- PLXND1 | c.4520G>A p.R1507Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); catalogued as rs766606211, COSV60719607; called by muse, mutect2
- PPT2 | c.814del p.A272Pfs*2 | Frame Shift Del (DEL) | VAF 65/193 reads (34%) | catalogued as COSV61353901, COSV61353944; called by mutect2, pindel, varscan2
- PRKN | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV58280622; called by muse, mutect2, varscan2
- PRR19 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56627864; called by muse, mutect2, varscan2
- PSG7 | c.217A>G p.R73G | Missense Mutation (SNP) | VAF 42/1100 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV68446663; called by muse, mutect2
- PSMB6 | c.171-1G>T p.X57_splice | Splice Site (SNP) | VAF 145/358 reads (41%) | catalogued as COSV54513445; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 236/310 reads (76%) | catalogued as rs146650273; called by pindel, varscan2
- PTGDR | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755045639, COSV60093637; called by muse, mutect2, varscan2
- RAB29 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 116/707 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs766320142, COSV52521950; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2213-1G>T p.X738_splice | Splice Site (SNP) | VAF 64/440 reads (15%) | catalogued as COSV62787264; called by muse, mutect2, varscan2
- RAD51C | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1378390389, COSV61676900; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGAPB | c.3574T>A p.F1192I | Missense Mutation (SNP) | VAF 164/396 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53444461; called by muse, mutect2, varscan2
- RBM27 | c.2006T>C p.V669A | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54594845; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 34/178 reads (19%) | catalogued as rs762006287; called by mutect2, varscan2
- RIC8A | c.1294G>A p.E432K (on ENST00000526104 / NM_001286134.1; = p.E438K on NM_021932.5) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.488); catalogued as rs372539478; called by mutect2, varscan2
- RNASE13 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 18/708 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58794382, COSV58794584; called by muse, mutect2
- RRP8 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54450775; called by muse, mutect2, varscan2
- RSBN1 | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV54735423; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 40/127 reads (31%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SBF2 | c.5323C>T p.R1775C | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs938347502, COSV56311975; ClinVar: uncertain significance; called by muse, mutect2
- SERPINB9 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66234366; called by muse, mutect2, varscan2
- SF3B2 | c.259-1G>A p.X87_splice | Splice Site (SNP) | VAF 6/120 reads (5%) | catalogued as COSV59430184; called by muse, mutect2
- SHROOM4 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs376604578, COSV56788702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC6 | c.842del p.P281Lfs*4 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as COSV100585657; called by mutect2, pindel, varscan2
- SIPA1L2 | c.1949T>G p.F650C | Missense Mutation (SNP) | VAF 112/227 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53400319; called by muse, mutect2, varscan2
- SLC14A1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.354); catalogued as rs367901541; called by muse, mutect2, varscan2
- SLC17A2 | c.361del p.M121Cfs*7 | Frame Shift Del (DEL) | VAF 78/214 reads (36%) | catalogued as rs770669846; called by mutect2, varscan2
- SLC17A6 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 12/298 reads (4%) | catalogued as COSV54141643; called by muse, mutect2
- SLC1A6 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs765825419, COSV55674306; called by muse, mutect2, varscan2
- SLC22A23 | c.1117A>G p.T373A | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66679613; called by muse, mutect2, varscan2
- SLIT2 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 173/471 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV56564291, COSV56596153; called by muse, mutect2, varscan2
- SNX2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV65349122; called by muse, mutect2, varscan2
- SNX8 | c.541-1G>T p.X181_splice | Splice Site (SNP) | VAF 7/66 reads (11%) | catalogued as COSV56130268; called by muse, mutect2, varscan2
- SOCS5 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV60606501; called by muse, mutect2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 30/155 reads (19%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYNE1 | c.21351+2T>C p.X7117_splice (on ENST00000367255 / NM_182961.4; = p.X7046_splice on NM_033071.3) | Splice Site (SNP) | VAF 62/350 reads (18%) | catalogued as COSV55108501; called by muse, mutect2, varscan2
- TAF1B | c.834del p.Y278* | Frame Shift Del (DEL) | VAF 48/154 reads (31%) | catalogued as COSV55155775, COSV99721849; called by mutect2, varscan2
- TEKT4 | c.1216G>C p.A406P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV54627012, COSV54628670; called by muse, mutect2, varscan2
- TENM4 | c.4396A>G p.T1466A | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.97); catalogued as COSV53672464; called by muse, mutect2, varscan2
- TET3 | c.3190G>A p.A1064T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs772345324, COSV69645820; called by muse, mutect2, varscan2
- THAP2 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.916); catalogued as COSV57350104; called by muse, mutect2, varscan2
- THOC2 | c.3823A>G p.K1275E | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.98); catalogued as COSV55556029; called by muse, mutect2, varscan2
- TLE1 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100918842, COSV64720352; called by muse, mutect2, varscan2
- TMEM183A | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65888226; called by muse, mutect2
- TOPORS | c.2261del p.N754Ifs*34 | Frame Shift Del (DEL) | VAF 106/316 reads (34%) | catalogued as rs755861530; called by mutect2, varscan2
- TRIM33 | c.2816T>A p.V939D | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV61826014; called by muse, mutect2, varscan2
- TRIM6 | c.644T>A p.I215N | Missense Mutation (SNP) | VAF 130/336 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.771); catalogued as COSV53479205; called by muse, mutect2, varscan2
- TRIO | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60086282; called by muse, mutect2, varscan2
- TRIP11 | c.5581del p.S1861Qfs*8 | Frame Shift Del (DEL) | VAF 92/646 reads (14%) | catalogued as rs958352599; called by mutect2, pindel, varscan2
- TRPM5 | c.3251G>T p.R1084I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV50151193; called by muse, mutect2, varscan2
- TRPM7 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57921704; called by muse, mutect2, varscan2
- TSR1 | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV52161904; called by muse, mutect2, varscan2
- TTN | c.84371C>T p.A28124V (on ENST00000591111; = p.A20700V on NM_003319.4) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | PolyPhen benign (0.041); catalogued as COSV60359861; called by muse, mutect2, varscan2
- TTN | c.39776T>A p.I13259N (on ENST00000591111; = p.I5835N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/172 reads (3%) | PolyPhen benign (0.011); catalogued as COSV60015104, COSV60359888; called by muse, mutect2
- TTN | c.16165G>A p.E5389K (on ENST00000591111; = p.E4462K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/217 reads (22%) | PolyPhen benign (0.001); catalogued as rs376593556, COSV59960214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUFM | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); catalogued as COSV57948532, COSV57949864; called by muse, mutect2, varscan2
- TXLNA | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65315224; called by muse, mutect2, varscan2
- TYW1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201171310, COSV62755749, COSV62756396; called by muse, mutect2, varscan2
- UPB1 | c.290A>G p.H97R | Missense Mutation (SNP) | VAF 215/570 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs774843626, COSV58116067; called by muse, mutect2, varscan2
- USP29 | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.714); catalogued as COSV54146847; called by muse, varscan2
- USP30 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774328555, COSV57451223; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as rs764735138; called by mutect2, varscan2
- VCAM1 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV54122171; called by muse, mutect2, varscan2
- WDCP | c.1094T>C p.L365S | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54593979; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WNK3 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201834658, COSV63615995; called by muse, mutect2, varscan2
- YY2 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63411155, COSV63412530; called by muse, mutect2, varscan2
- ZC3H7B | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV60964796; called by muse, mutect2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 92/263 reads (35%) | catalogued as rs760215323; called by mutect2, pindel, varscan2
- ZDHHC6 | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.216); catalogued as COSV65565345; called by muse, mutect2, varscan2
- ZNF608 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs148666540; called by muse, mutect2, varscan2
- ZNF91 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 193/524 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs202143348; called by muse, mutect2, varscan2
- ZRANB2 | c.901del p.R301Dfs*38 (on ENST00000370920 / NM_203350.3; = p.R301Dfs*12 on NM_005455.5) | Frame Shift Del (DEL) | VAF 103/321 reads (32%) | catalogued as COSV54672452; called by mutect2, pindel, varscan2
- ACACA | c.2194G>A p.V732M | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- AGTPBP1 | c.163dup p.T55Nfs*31 | Frame Shift Ins (INS) | VAF 41/131 reads (31%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.12928del p.V4310Cfs*17 | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2949del p.K983Nfs*4 | Frame Shift Del (DEL) | VAF 64/311 reads (21%) | called by mutect2, varscan2
- ARHGAP17 | c.2432del p.P811Hfs*26 (on ENST00000289968 / NM_001006634.3; = p.P733Hfs*26 on NM_018054.6) | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by pindel, varscan2
- ARID1A | c.3281dup p.Q1095Afs*10 | Frame Shift Ins (INS) | VAF 61/166 reads (37%) | called by mutect2, pindel, varscan2
- ARID5B | c.1330_1337dup p.H446Qfs*36 | Frame Shift Ins (INS) | VAF 298/794 reads (38%) | called by mutect2, varscan2
- ATP2B4 | c.584del p.N195Tfs*32 | Frame Shift Del (DEL) | VAF 59/387 reads (15%) | called by mutect2, pindel, varscan2
- BTNL8 | c.747del p.F249Lfs*6 | Frame Shift Del (DEL) | VAF 121/841 reads (14%) | called by mutect2, pindel, varscan2
- C18orf54 | c.308del p.K103Sfs*16 | Frame Shift Del (DEL) | VAF 43/131 reads (33%) | called by mutect2, pindel, varscan2
- C6orf118 | c.360dup p.S121Qfs*2 | Frame Shift Ins (INS) | VAF 10/97 reads (10%) | called by mutect2, pindel, varscan2
- CLRN1 | c.591del p.F197Lfs*5 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | called by mutect2, pindel, varscan2
- CYP3A7-CYP3A51P | c.1585dup p.C529Lfs*? | Frame Shift Ins (INS) | VAF 34/86 reads (40%) | called by mutect2, pindel, varscan2
- DENND2C | c.473del p.P158Qfs*5 | Frame Shift Del (DEL) | VAF 96/307 reads (31%) | called by mutect2, pindel, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 19/172 reads (11%) | called by mutect2, pindel, varscan2
- EP300 | c.7040dup p.H2348Tfs*31 | Frame Shift Ins (INS) | VAF 36/189 reads (19%) | called by mutect2, pindel, varscan2
- ESCO1 | c.55del p.S19Vfs*17 | Frame Shift Del (DEL) | VAF 31/225 reads (14%) | called by mutect2, pindel, varscan2
- FBXO39 | c.486del p.K162Nfs*8 | Frame Shift Del (DEL) | VAF 35/204 reads (17%) | called by mutect2, pindel, varscan2
- GABRE | c.1215del p.F405Lfs*86 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- GAN | c.839_841del p.G280del | In Frame Del (DEL) | VAF 67/205 reads (33%) | called by mutect2, pindel, varscan2
- GLI1 | c.1700del p.P567Lfs*46 | Frame Shift Del (DEL) | VAF 31/106 reads (29%) | called by pindel, varscan2
- GOLGA4 | c.1796del p.N599Ifs*36 | Frame Shift Del (DEL) | VAF 14/143 reads (10%) | called by mutect2, pindel, varscan2
- GPATCH2 | c.1253dup p.N418Kfs*43 | Frame Shift Ins (INS) | VAF 82/278 reads (29%) | called by mutect2, pindel, varscan2
- HEXD | c.1048dup p.T350Nfs*5 | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGLV5-48 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- LARS2 | c.1481del p.P494Hfs*9 | Frame Shift Del (DEL) | VAF 38/122 reads (31%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.678dup p.E227* | Frame Shift Ins (INS) | VAF 18/137 reads (13%) | called by mutect2, varscan2
- MED13L | c.2309del p.N770Mfs*31 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- NSRP1 | c.257del p.K86Rfs*23 | Frame Shift Del (DEL) | VAF 53/147 reads (36%) | called by mutect2, varscan2
- ORC4 | c.613dup p.R205Kfs*24 | Frame Shift Ins (INS) | VAF 33/164 reads (20%) | called by mutect2, pindel, varscan2
- PASD1 | c.1051del p.A351Lfs*26 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | called by mutect2, pindel, varscan2
- PGA4 | c.1062dup p.T355Hfs*11 | Frame Shift Ins (INS) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- PGLYRP2 | c.1700dup p.R568Kfs*? | Frame Shift Ins (INS) | VAF 24/173 reads (14%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1212_1215delinsT p.L404_I405delinsF (on ENST00000521381 / NM_181523.3; = p.L134_I135delinsF on NM_181504.4) | In Frame Del (DEL) | VAF 41/103 reads (40%) | called by pindel, varscan2*
- PPFIA1 | c.2582dup p.H862Afs*2 | Frame Shift Ins (INS) | VAF 20/146 reads (14%) | called by mutect2, varscan2
- PRB3 | c.812del p.P271Hfs*78 (on ENST00000381842; = p.P313Hfs*? on NM_006249.5) | Frame Shift Del (DEL) | VAF 83/688 reads (12%) | called by mutect2, pindel, varscan2
- PRDM2 | c.522del p.K174Nfs*17 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- PTPN14 | c.515dup p.L172Ffs*31 | Frame Shift Ins (INS) | VAF 42/362 reads (12%) | called by mutect2, pindel, varscan2
- REV3L | c.5974dup p.I1992Nfs*33 | Frame Shift Ins (INS) | VAF 79/405 reads (20%) | called by mutect2, varscan2
- RSBN1L | c.641del p.K214Rfs*5 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- SCRN2 | c.776del p.G259Afs*6 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- SNCG | c.76del p.V26* | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- SPTY2D1 | c.1454del p.P485Rfs*12 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- TAF3 | c.2186_2187dup p.R730Sfs*17 | Frame Shift Ins (INS) | VAF 136/322 reads (42%) | called by mutect2, varscan2
- TAOK2 | c.2255del p.P752Rfs*20 | Frame Shift Del (DEL) | VAF 52/140 reads (37%) | called by mutect2, pindel, varscan2
- TEKT5 | c.923dup p.N308Kfs*18 | Frame Shift Ins (INS) | VAF 67/180 reads (37%) | called by mutect2, pindel, varscan2
- USP34 | c.1193del p.L398Wfs*7 | Frame Shift Del (DEL) | VAF 99/601 reads (16%) | called by mutect2, pindel, varscan2
- WDR13 | c.143del p.P48Qfs*8 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- ZFHX3 | c.5037dup p.L1680Tfs*7 | Frame Shift Ins (INS) | VAF 78/235 reads (33%) | called by mutect2, pindel, varscan2
- ZNF827 | c.3070del p.C1024Afs*33 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel
- ACO2 | c.2199C>T p.T733= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV53445511; called by muse, mutect2
- ALG13 | c.1209C>T p.S403= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs773641755, COSV52645198; called by muse, mutect2, varscan2
- ALYREF | c.351G>C p.V117= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV58669242; called by muse, mutect2, varscan2
- ASPM | c.3540T>C p.N1180= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV54139046; called by muse, mutect2, varscan2
- ATP2A3 | c.1497G>A p.T499= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs575526294, COSV59235343; called by muse, mutect2
- ATP2B2 | c.1023C>T p.D341= (on ENST00000352432; = p.D307= on NM_001683.5) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs369726075, COSV59504958; called by muse, mutect2
- CALCRL | c.864C>A p.T288= | Silent (SNP) | VAF 39/283 reads (14%) | catalogued as COSV66477683; called by muse, mutect2, varscan2
- CHD5 | c.3237G>A p.R1079= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV52425394; called by muse, mutect2
- CHPF | c.1392G>A p.T464= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs778272074, COSV60536890; called by muse, mutect2, varscan2
- CIB3 | c.36G>A p.Q12= | Silent (SNP) | VAF 10/295 reads (3%) | catalogued as COSV54167705; called by muse, mutect2
- CIC | c.288G>C p.R96= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV50668227; called by muse, mutect2
- CNOT1 | c.3834C>T p.N1278= | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as COSV55322489; called by muse, mutect2
- COL24A1 | c.879C>A p.I293= | Silent (SNP) | VAF 45/243 reads (19%) | catalogued as COSV65304906, COSV65309491, COSV65314542; called by muse, mutect2, varscan2
- CRNN | c.990C>T p.I330= | Silent (SNP) | VAF 24/606 reads (4%) | catalogued as COSV55123063; called by muse, mutect2
- CSMD3 | c.8406A>G p.S2802= (on ENST00000297405 / NM_001363185.1; = p.S2633= on NM_052900.3) | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as rs1183439403, COSV52324856; called by muse, mutect2, varscan2
- DMBT1 | c.7572C>T p.V2524= (on ENST00000338354 / NM_001377530.1; = p.V1767= on NM_004406.3) | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV57534536; called by muse, mutect2, varscan2
- ECM1 | c.1347C>T p.C449= | Silent (SNP) | VAF 105/366 reads (29%) | catalogued as COSV60875307; called by muse, mutect2, varscan2
- EML1 | c.1149C>T p.D383= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as COSV51753166; called by muse, mutect2, varscan2
- EPAS1 | c.138T>C p.S46= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as rs1419595958, COSV55390521; called by muse, mutect2, varscan2
- GDF10 | c.1059G>A p.Q353= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- GP1BA | c.1551T>C p.N517= | Silent (SNP) | VAF 163/407 reads (40%) | catalogued as COSV56700933; called by muse, mutect2, varscan2
- GSTP1 | c.400C>T p.L134= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs373551358; called by mutect2, varscan2
- H1-1 | c.273A>G p.V91= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV55120620; called by muse, mutect2
- HUWE1 | c.6327A>G p.L2109= | Silent (SNP) | VAF 69/177 reads (39%) | catalogued as COSV53364401; called by muse, mutect2, varscan2
- IGF1R | c.1473C>T p.D491= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs377404946, COSV51270806; called by muse, mutect2, varscan2
- IGSF9 | c.1323C>T p.S441= (on ENST00000368094 / NM_001135050.2; = p.S425= on NM_020789.4) | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs141409628; called by muse, mutect2, varscan2
- INTS5 | c.123C>T p.G41= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs746914059, COSV57953686; called by muse, mutect2, varscan2
- KBTBD6 | c.792C>T p.C264= | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as COSV65271468; called by muse, mutect2
- KCNC2 | c.1233C>T p.N411= | Silent (SNP) | VAF 79/199 reads (40%) | catalogued as rs200648638, COSV100128147, COSV54373983; called by muse, mutect2, varscan2
- KLHL13 | c.195T>C p.P65= | Silent (SNP) | VAF 30/230 reads (13%) | catalogued as COSV53253304; called by muse, mutect2, varscan2
- MADD | c.789G>A p.G263= | Silent (SNP) | VAF 4/92 reads (4%) | catalogued as COSV60628822; called by muse, mutect2
- MAGEA11 | c.28C>T p.L10= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV60758284, COSV60758982; called by muse, mutect2
- MAP1LC3C | c.312C>A p.I104= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs944038124, COSV61804122; called by muse, mutect2, varscan2
- MTOR | c.894G>A p.K298= | Silent (SNP) | VAF 77/284 reads (27%) | catalogued as COSV63878505; called by muse, mutect2, varscan2
- MUSK | c.63T>C p.T21= | Silent (SNP) | VAF 119/591 reads (20%) | catalogued as rs1466148518, COSV51897219; called by muse, mutect2, varscan2
- MYPN | c.3045C>T p.G1015= | Silent (SNP) | VAF 65/167 reads (39%) | catalogued as COSV62739780; called by muse, mutect2, varscan2
- NCAM1 | c.651G>A p.R217= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as rs975386483, COSV57509729, COSV57525238; called by muse, mutect2, varscan2
- NEURL1 | c.381C>T p.S127= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV63915540; called by muse, mutect2, varscan2
- NIP7 | c.99C>T p.G33= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV54743631; called by muse, mutect2, varscan2
- OR13C5 | c.348C>T p.G116= | Silent (SNP) | VAF 38/390 reads (10%) | catalogued as rs768261171, COSV66165350; called by muse, mutect2
- PCDHA10 | c.642T>C p.T214= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV56547491; called by muse, mutect2
- PCDHA12 | c.615G>A p.T205= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV56482447; called by muse, mutect2, varscan2
- PCDHGA5 | c.735C>T p.S245= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs1300257401, COSV53896918; called by muse, mutect2, varscan2
- PCDHGB5 | c.2217C>T p.Y739= | Silent (SNP) | VAF 106/236 reads (45%) | catalogued as COSV54037224; called by muse, mutect2, varscan2
- PEX12 | c.561G>A p.Q187= | Silent (SNP) | VAF 69/214 reads (32%) | catalogued as COSV56778978; called by muse, mutect2, varscan2
- PGPEP1L | c.220C>A p.R74= | Silent (SNP) | VAF 72/178 reads (40%) | catalogued as rs200266269, COSV66710123; called by muse, mutect2, varscan2
- PLD1 | c.90G>A p.T30= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as rs750439678, COSV60567006; called by muse, mutect2, varscan2
- PLSCR3 | c.360C>T p.A120= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- POLR2A | c.507T>C p.P169= | Silent (SNP) | VAF 12/268 reads (4%) | catalogued as COSV59496204; called by muse, mutect2
- PRKCD | c.486C>T p.I162= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs552199774, COSV57851805; called by muse, mutect2, varscan2
- PRRC2B | c.6129G>A p.Q2043= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs894515161, COSV57645955, COSV57646462; called by muse, mutect2, varscan2
- R3HDM1 | c.1116G>T p.L372= | Silent (SNP) | VAF 133/287 reads (46%) | catalogued as COSV51533038; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3048C>T p.G1016= | Silent (SNP) | VAF 11/171 reads (6%) | catalogued as rs374571704, COSV54762503; called by muse, mutect2
- SERINC1 | c.531A>G p.S177= | Silent (SNP) | VAF 8/248 reads (3%) | catalogued as rs1248587402, COSV60102931; called by muse, mutect2
- SLC28A2 | c.1305C>A p.A435= | Silent (SNP) | VAF 84/206 reads (41%) | catalogued as COSV61665355; called by muse, mutect2, varscan2
- SPIC | c.24G>A p.K8= | Silent (SNP) | VAF 37/239 reads (15%) | catalogued as rs761616183, COSV54692802; called by muse, mutect2, varscan2
- SPTAN1 | c.4830C>T p.I1610= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1402875849, COSV63989922; called by muse, mutect2, varscan2
- SYNDIG1L | c.537T>C p.A179= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV59048552; called by muse, mutect2, varscan2
- SYT6 | c.1425C>T p.G475= (on ENST00000610222 / NM_001366225.1; = p.G390= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as COSV65773910, COSV65776309; called by muse, mutect2, varscan2
- TOP3A | c.366C>T p.C122= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV58181193; called by muse, mutect2, varscan2
- TRAJ59 | c.42G>A p.T14= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs769471835; called by muse, varscan2
- UFSP2 | c.663C>T p.G221= | Silent (SNP) | VAF 89/199 reads (45%) | catalogued as COSV52993001; called by muse, mutect2, varscan2
- VWA8 | c.309G>A p.G103= | Silent (SNP) | VAF 13/327 reads (4%) | catalogued as rs1233309267, COSV55702160; called by muse, mutect2
- XPO6 | c.132C>A p.A44= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as COSV58971793; called by muse, mutect2, varscan2
- ZBTB33 | c.987G>A p.E329= | Silent (SNP) | VAF 10/286 reads (3%) | catalogued as COSV58534483, COSV58534897; called by muse, mutect2
- ZBTB40 | c.3387G>A p.K1129= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV65146457; called by muse, mutect2, varscan2
- ARPP19P2 | n.222C>T | RNA (SNP) | VAF 115/282 reads (41%) | catalogued as rs547315470; called by muse, mutect2, varscan2
- LINC00922 | n.825dup | RNA (INS) | VAF 157/438 reads (36%) | called by mutect2, pindel, varscan2
- NRXN3 | c.602-5369del | Intron (DEL) | VAF 34/116 reads (29%) | called by mutect2, varscan2
- PLEKHA8P1 | n.1595C>T | RNA (SNP) | VAF 78/219 reads (36%) | catalogued as rs180755151; called by muse, mutect2, varscan2
- POLA1 | c.2947-21036G>A | Intron (SNP) | VAF 13/455 reads (3%) | called by muse, mutect2
- RGS3 | c.3081-379del | Intron (DEL) | VAF 26/54 reads (48%) | catalogued as rs752722940; called by mutect2, varscan2
- SNORD116-16 | n.70T>C | RNA (SNP) | VAF 167/418 reads (40%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | chr17:76561109 C>T | 3'Flank (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- TUBGCP3 | c.2448+131T>C | Intron (SNP) | VAF 17/74 reads (23%) | catalogued as COSV56191533; called by muse, mutect2, varscan2
